Somatic mutation profile of tumor specimen TCGA-A4-A5Y1-01A (aliquot TCGA-A4-A5Y1-01A-11D-A28G-10) from TCGA case TCGA-A4-A5Y1, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 75.4 years (27,541 days).
Specimen TCGA-A4-A5Y1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4601689a-1f2a-4b78-95b7-7763e1c60da2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-A5Y1-11A (Solid Tissue Normal), aliquot TCGA-A4-A5Y1-11A-11D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1333fc60-ae92-45bd-a2b7-3d2660c7d4f2

The open-access MAF lists 75 somatic variants for this specimen: 58 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 43, Silent 17, Nonsense Mutation 6, Frame Shift Del 5, Frame Shift Ins 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B1 | c.584T>G p.L195R | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54894480; called by muse, mutect2, varscan2
- ATAD5 | c.4648A>T p.K1550* | Nonsense Mutation (SNP) | VAF 51/86 reads (59%) | catalogued as COSV58979886; called by muse, mutect2, varscan2
- BAIAP3 | c.3109C>A p.L1037M | Missense Mutation (SNP) | VAF 97/148 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99136225; called by mutect2, varscan2
- BOD1L1 | c.5878A>C p.S1960R | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV50081568; called by muse, mutect2
- BPIFB1 | c.1254+1G>A p.X418_splice | Splice Site (SNP) | VAF 66/180 reads (37%) | catalogued as COSV53609157; called by muse, mutect2, varscan2
- CAMTA2 | c.3013C>T p.P1005S | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs189574616, COSV52779823; called by muse, mutect2, varscan2
- CATSPERB | c.71A>G p.Y24C | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs757379503, COSV56436377; called by muse, mutect2, varscan2
- CD1C | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.381); catalogued as rs1005150918, COSV63807161; called by muse, mutect2, varscan2
- CSF2RA | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 118/356 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV62627096; called by muse, mutect2, varscan2
- CUBN | c.323G>T p.S108I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV64702075; called by muse, mutect2, varscan2
- DEPDC1B | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs752619351, COSV54007966; called by mutect2, varscan2
- EHMT1 | c.3374G>A p.R1125K | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs1377925157, COSV71778792; called by muse, mutect2, varscan2
- FRMPD4 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 93/110 reads (85%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV66224505; called by muse, mutect2, varscan2
- FSIP2 | c.17560C>T p.Q5854* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as rs1260243219, COSV58101663; called by muse, mutect2, varscan2
- GPR87 | c.602T>A p.V201D | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.283); catalogued as rs1559993717, COSV53464748; called by muse, mutect2, varscan2
- GRM4 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV65214328; called by muse, varscan2
- KIAA1109 | c.12182T>A p.V4061E | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV52695838; called by muse, mutect2, varscan2
- KLHL17 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 106/155 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV58533859; called by muse, varscan2
- KLK5 | c.677A>C p.D226A | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.455); catalogued as COSV60451777; called by muse, mutect2, varscan2
- KMT2D | c.5558C>T p.A1853V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs1180828668, COSV56492438; called by muse, mutect2
- KNL1 | c.1417A>T p.R473* (on ENST00000346991 / NM_170589.5; = p.R447* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 56/137 reads (41%) | catalogued as COSV61161103; called by muse, mutect2, varscan2
- KRTAP26-1 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as COSV62129442; called by muse, mutect2, varscan2
- MYH7 | c.4459G>A p.A1487T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as rs766909770, COSV62524750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYT1 | c.2654A>T p.K885M | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV60514985; called by muse, mutect2, varscan2
- NAA10 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV64170711; called by muse, mutect2, varscan2
- OR13F1 | c.918T>G p.I306M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV58252784; called by muse, mutect2, varscan2
- P2RX1 | c.177C>G p.S59R | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV56656216; called by muse, mutect2, varscan2
- PCSK2 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV52744683; called by muse, mutect2, varscan2
- PCSK4 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.066); catalogued as rs377189780, COSV56301661; called by muse, mutect2, varscan2
- PDXDC1 | c.1720C>T p.L574F | Missense Mutation (SNP) | VAF 131/189 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV55076177; called by muse, mutect2, varscan2
- PIAS1 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV51039051; called by muse, mutect2, varscan2
- PIEZO2 | c.6973A>T p.K2325* | Nonsense Mutation (SNP) | VAF 67/245 reads (27%) | catalogued as COSV53295192; called by muse, mutect2, varscan2
- PKD1 | c.8536A>G p.T2846A | Missense Mutation (SNP) | VAF 62/81 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as CM164775, COSV51927098; called by muse, mutect2, varscan2
- PLXNA3 | c.5528C>T p.T1843M | Missense Mutation (SNP) | VAF 168/193 reads (87%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.595); catalogued as rs782174023, COSV63754382; called by muse, mutect2, varscan2
- PRDM7 | c.975T>A p.D325E | Missense Mutation (SNP) | VAF 110/179 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57987993; called by muse, mutect2, varscan2
- RBBP8 | c.2627C>G p.P876R | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV59093803, COSV59096383; called by muse, mutect2, varscan2
- SH3BP4 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV60642688, COSV60646872; called by muse, mutect2, varscan2
- SHCBP1L | c.1175C>A p.T392N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV62357535; called by muse, mutect2, varscan2
- SLC25A28 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.377); catalogued as COSV65125767; called by muse, mutect2, varscan2
- SLC26A5 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59706601; called by muse, mutect2, varscan2
- SMC6 | c.3152A>C p.Q1051P | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61178870; called by muse, varscan2
- SPTAN1 | c.5348A>G p.K1783R | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63990106; called by muse, mutect2, varscan2
- TBCB | c.77A>T p.K26M | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV52900839; called by muse, mutect2, varscan2
- TNP1 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as rs561435538, COSV52696595; called by muse, mutect2, varscan2
- TP53I13 | c.593C>G p.S198C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV56404313; called by muse, mutect2, varscan2
- TTN | c.32126A>C p.H10709P (on ENST00000591111; = p.H9782P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/100 reads (53%) | PolyPhen benign (0); catalogued as COSV60388675; called by muse, mutect2, varscan2
- VPS13C | c.10888G>T p.E3630* (on ENST00000644861 / NM_020821.3; = p.E3587* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 38/106 reads (36%) | catalogued as COSV51427902; called by muse, mutect2, varscan2
- YLPM1 | c.1365G>A p.W455* | Nonsense Mutation (SNP) | VAF 110/149 reads (74%) | catalogued as COSV53121906; called by muse, mutect2, varscan2
- ZNF280A | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 93/112 reads (83%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV57482604; called by muse, mutect2, varscan2
- FGGY | c.878_891del p.C293Lfs*31 | Frame Shift Del (DEL) | VAF 94/175 reads (54%) | called by mutect2, varscan2
- HMCN2 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ITGA6 | c.2383del p.S795Vfs*16 (on ENST00000442250; = p.S756Vfs*16 on NM_000210.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- ITPRID2 | c.700dup p.Y234Lfs*11 | Frame Shift Ins (INS) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- PDS5A | c.3143_3150del p.A1048Efs*18 | Frame Shift Del (DEL) | VAF 39/93 reads (42%) | called by pindel, varscan2*
- PSIP1 | c.1179del p.H393Qfs*4 | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- SENP5 | c.901dup p.C301Lfs*25 | Frame Shift Ins (INS) | VAF 39/99 reads (39%) | called by mutect2, pindel, varscan2
- SETD2 | c.6415del p.Q2139Nfs*8 | Frame Shift Del (DEL) | VAF 69/97 reads (71%) | called by mutect2, pindel*, varscan2
- TRIM44 | c.297dup p.E100* | Frame Shift Ins (INS) | VAF 52/230 reads (23%) | called by mutect2, pindel, varscan2
- ABHD12B | c.792C>T p.N264= (on ENST00000337334 / NM_001206673.2; = p.N187= on NM_181533.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/64 reads (67%) | catalogued as rs1245305206, COSV53589161; called by muse, mutect2, varscan2
- AGFG1 | c.1044C>G p.G348= | Silent (SNP) | VAF 119/200 reads (60%) | catalogued as COSV59515131; called by muse, mutect2, varscan2
- AMBRA1 | c.3675C>T p.G1225= (on ENST00000458649 / NM_001367468.1; = p.G1135= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as COSV54063607; called by muse, mutect2, varscan2
- FAHD1 | c.363G>T p.L121= | Silent (SNP) | VAF 38/256 reads (15%) | catalogued as COSV66900693; called by muse, mutect2, varscan2
- FANCI | c.3681A>T p.G1227= (on ENST00000310775 / NM_001376911.1; = p.G1167= on NM_018193.3) | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV51525761; called by muse, mutect2, varscan2
- FBL | c.336C>T p.V112= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs750801232, COSV55683176, COSV55684221; called by muse, mutect2, varscan2
- H1-2 | c.561A>G p.K187= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as rs1436157574, COSV59193028; called by muse, mutect2
- IL16 | c.198A>G p.T66= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as rs775697249, COSV57268953; called by muse, mutect2, varscan2
- KCNA4 | c.1332A>G p.R444= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV60250534; called by muse, mutect2, varscan2
- KCNQ1 | c.1710C>G p.P570= | Silent (SNP) | VAF 47/169 reads (28%) | catalogued as rs1322520867, CD057258, COSV50135809; called by muse, mutect2, varscan2
- MPP5 | c.1450T>C p.L484= | Silent (SNP) | VAF 28/38 reads (74%) | catalogued as COSV55533165; called by muse, mutect2, varscan2
- PCDHGB3 | c.1704G>A p.G568= | Silent (SNP) | VAF 69/267 reads (26%) | catalogued as COSV54046759; called by muse, mutect2, varscan2
- SELENOO | c.1125C>T p.Y375= | Silent (SNP) | VAF 97/139 reads (70%) | catalogued as COSV66600683; called by muse, mutect2, varscan2
- SHPK | c.1210C>A p.R404= | Silent (SNP) | VAF 92/158 reads (58%) | catalogued as COSV56650683; called by muse, mutect2, varscan2
- SPX | c.177G>C p.R59= | Silent (SNP) | VAF 142/191 reads (74%) | catalogued as COSV57021923; called by muse, mutect2, varscan2
- STAU2 | c.1506T>C p.Y502= (on ENST00000524300 / NM_001164380.2; = p.Y470= on NM_014393.2) | Silent (SNP) | VAF 57/131 reads (44%) | catalogued as COSV63312514; called by muse, mutect2, varscan2
- TENM3 | c.5838C>T p.V1946= | Silent (SNP) | VAF 63/190 reads (33%) | catalogued as COSV69321272; called by muse, mutect2, varscan2
